Gene-level copy-number profile of tumor specimen TCGA-A2-A0YM-01A from TCGA case TCGA-A2-A0YM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.0 years (24,831 days).
Specimen TCGA-A2-A0YM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.356ec0ad-a065-44db-8a4d-218efff4c3b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0YM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdf7c652-17d3-4870-8e32-9bc4146d011a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 942; copy number 2: 14,195; copy number 3: 24,766; copy number 4: 8,679; copy number 5: 3,808; copy number 6: 5,245; copy number 7: 1,039; copy number 8: 189; copy number 9: 148; copy number 10: 128; copy number 11: 109; copy number 12: 67; copy number 13: 17; copy number 14: 48; copy number 16: 93; copy number 17: 44; copy number 18: 119; copy number 20: 1; copy number 22: 11; copy number 26: 41; copy number 29: 124.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0YM-01A-11D-A107-01): tumor purity 0.58, ploidy 3.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,178 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,506,365–42,035,925, 1 gene, copy number 26 (within-gene range 3–26): HIVEP3.
- chr1:41,585,306–44,355,260, 97 genes, copy number 12–26 (within-gene range 3–26) (broad region; genes not listed).
- chr1:74,026,015–89,525,472, 225 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:118,883,046–121,580,524, 78 genes, copy number 18 (broad region; genes not listed).
- chr1:164,343,005–168,075,843, 82 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:171,841,498–172,418,466, 1 gene, copy number 14 (within-gene range 5–14): DNM3.
- chr1:172,138,397–172,613,534, 10 genes, copy number 14: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P.
- chr1:223,856,579–225,399,292, 31 genes, copy number 10: PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14.
- chr1:229,249,636–229,508,341, 11 genes, copy number 10 (within-gene range 4–10): TMEM78, AL162595.1, RAB4A, AL117350.1, CCSAP, RNU6-180P, RN7SKP276, AL160004.2, ACTA1, NUP133, AL160004.1.
- chr6:44,273,194–44,378,957, 1 gene, copy number 12 (within-gene range 6–12): AL353588.1.
- chr6:44,298,731–46,761,158, 32 genes, copy number 8–12: AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1.
- chr6:49,946,021–57,222,307, 120 genes, copy number 7–16 (broad region; genes not listed).
- chr6:62,460,940–63,779,336, 19 genes, copy number 8: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–64,412,779, 4 genes, copy number 8: AL354719.1, SCAT8, GCNT1P4, AL357375.1.
- chr7:112,422,887–113,494,870, 18 genes, copy number 10 (within-gene range 5–10): IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, AC073348.2.
- chr7:114,297,114–114,419,875, 2 genes, copy number 12: AC073626.2, AC073626.1.
- chr7:127,997,597–130,442,433, 94 genes, copy number 9–16 (broad region; genes not listed).
- chr8:37,843,268–38,853,028, 41 genes, copy number 18: BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr8:41,426,655–47,202,897, 105 genes, copy number 7 (broad region; genes not listed).
- chr10:33,759,713–35,572,669, 27 genes, copy number 7 (within-gene range 4–7): LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1.
- chr17:19,020,656–22,706,703, 187 genes, copy number 7 (broad region; genes not listed).
- chr18:894,435–4,455,307, 66 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr18:5,567,130–7,117,797, 29 genes, copy number 14 (within-gene range 6–14): AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1.
- chr18:9,102,630–14,054,761, 151 genes, copy number 11–17 (broad region; genes not listed).
- chr18:14,074,912–14,091,019, 2 genes, copy number 17: AC006557.4, AC006557.1.
- chr18:25,818,234–27,190,698, 27 genes, copy number 7 (within-gene range 4–7): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2.
- chr18:29,256,817–30,414,073, 6 genes, copy number 9 (within-gene range 5–9): AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F.
- chr19:27,638,483–34,577,701, 153 genes, copy number 7–9 (broad region; genes not listed).
- chr20:760,080–916,334, 4 genes, copy number 7: SLC52A3, FAM110A, RPS10P5, ANGPT4.
- chr20:25,919,499–26,251,546, 13 genes, copy number 7: CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr21:10,328,411–25,361,868, 194 genes, copy number 7–29 (broad region; genes not listed).
- chr21:32,497,967–45,074,165, 346 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr21:45,100,487–45,101,094, 1 gene, copy number 8: AL133499.1.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
